Somatic mutation profile of tumor specimen TARGET-20-PANHYK-09A (aliquot TARGET-20-PANHYK-09A-02D) from TARGET case TARGET-20-PANHYK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,191 days).
Specimen TARGET-20-PANHYK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d1cbe66-7f0f-41a6-8aee-52da48ec244f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANHYK-14A (Bone Marrow Normal), aliquot TARGET-20-PANHYK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42c80097-4111-4421-841e-299cf60df8c1

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>A p.N822K | Missense Mutation (SNP) | VAF 23/177 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- HACE1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139231075; called by muse, mutect2
- HOXB3 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs777244686, COSV57487932; called by muse, mutect2, varscan2
- SMC3 | c.2795T>C p.L932P | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758156711, COSV62421630; called by muse, mutect2, varscan2
